TCGA case TCGA-W5-AA38 — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/48d17b17-348c-405a-ae92-f190372a3aac

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (2)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 55.5 years (20,285 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,471 days (4.0 years); Child pugh classification: A; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Liver. Age at diagnosis: 56.6 years (20,662 days); Days to diagnosis: 377 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Residual disease: R0.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 377 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 377 days (1.0 years).
- Days to follow up: 964 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 1,471 days (4.0 years); Disease response: Tumor Free.
- ECOG performance status: 1.

Molecular and laboratory tests
- CA19-9: 199 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 55.
- Alpha Fetoprotein 2.2 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.1].
- Platelets 239 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Total Bilirubin 0.3 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Albumin 4.8 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 168 cm; BMI: 25.9.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer.
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA38-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-W5-AA38-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-W5-AA38-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W5-AA38-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Lobectomy.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,471 days; disease-specific survival: no event (censored), 1,471 days; disease-free interval: event (new tumor event after initially disease-free), 377 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 377 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W5-AA38-01A-11D-A416-01): tumor purity 0.69, ploidy 1.71, whole-genome doublings 0.
